Somatic mutation profile of tumor specimen C3N-06050-02 (aliquot CPT0438970009) from CPTAC case C3N-06050, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 75.5 years (27,590 days).
Specimen C3N-06050-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b5dce107-1af5-4332-8e78-f01f6e89b376.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-06050-31 (Blood Derived Normal), aliquot CPT0444860005; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a1e5490b-2e5c-48c4-af10-a3e00b525ade

The open-access MAF lists 489 somatic variants for this specimen: 313 protein-altering or splice-affecting, 159 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 284, Silent 159, Nonsense Mutation 21, Intron 11, Splice Region 3, 5'Flank 2, 3'UTR 2, Splice Site 2, In Frame Del 1, Translation Start Site 1, 3'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DDX3X | c.1420C>T p.R474C (on ENST00000399959; = p.R475C on NM_001356.5) | Missense Mutation (SNP) | VAF 89/180 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1064794574, CM158049, COSV67864105; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 328/618 reads (53%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.13709C>T p.S4570F | Missense Mutation (SNP) | VAF 67/314 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV68944042; called by muse, mutect2, varscan2
- AC127029.3 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 64/258 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.456); catalogued as rs764929278, COSV60111846; called by muse, mutect2, varscan2
- ACAD10 | c.796C>T p.P266S | Missense Mutation (SNP) | VAF 66/335 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.06); catalogued as COSV100564298; called by muse, mutect2, varscan2
- ADGRB3 | c.3571G>A p.D1191N | Missense Mutation (SNP) | VAF 42/203 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV53235644; called by muse, mutect2, varscan2
- ADGRF5 | c.2855C>G p.T952R | Missense Mutation (SNP) | VAF 78/381 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as COSV51935488; called by muse, mutect2, varscan2
- ADGRG4 | c.5780C>T p.T1927I | Missense Mutation (SNP) | VAF 128/218 reads (59%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV54967835; called by muse, mutect2, varscan2
- ADGRV1 | c.2542G>A p.G848R | Missense Mutation (SNP) | VAF 49/197 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs1156605972; called by muse, mutect2, varscan2
- AIFM3 | c.991C>T p.R331* | Nonsense Mutation (SNP) | VAF 61/303 reads (20%) | catalogued as rs201655926; called by muse, mutect2, varscan2
- ALG10B | c.1246C>T p.R416C | Missense Mutation (SNP) | VAF 44/274 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375350214, COSV58142173; called by muse, mutect2, varscan2
- AMTN | c.620G>A p.G207E | Missense Mutation (SNP) | VAF 39/221 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.084); catalogued as COSV59489674; called by muse, mutect2, varscan2
- ANKK1 | c.1664C>T p.A555V | Missense Mutation (SNP) | VAF 101/312 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV58273331; called by muse, mutect2, varscan2
- ANKRD30A | c.1582G>A p.E528K (on ENST00000611781; = p.E472K on NM_052997.2) | Missense Mutation (SNP) | VAF 44/230 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.014); catalogued as rs267602480; called by muse, mutect2, varscan2
- ANKRD30A | c.3283G>A p.E1095K (on ENST00000611781; = p.E1039K on NM_052997.2) | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.899); catalogued as rs762947956, COSV64620998; called by muse, mutect2, varscan2
- APAF1 | c.2414C>T p.S805L (on ENST00000551964 / NM_181861.2; = p.S794L on NM_001160.3) | Missense Mutation (SNP) | VAF 73/385 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); catalogued as rs375207439; called by muse, mutect2, varscan2
- ARID2 | c.1624C>T p.R542* | Nonsense Mutation (SNP) | VAF 50/218 reads (23%) | catalogued as COSV57595668; called by muse, mutect2, varscan2
- BRINP2 | c.1975G>A p.E659K | Missense Mutation (SNP) | VAF 64/261 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.202); catalogued as COSV64179297; called by muse, mutect2, varscan2
- BSN | c.6935C>T p.P2312L | Missense Mutation (SNP) | VAF 52/377 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as rs1395948525; called by muse, mutect2, varscan2
- BTC | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 47/194 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs1389771868; called by muse, mutect2, varscan2
- C1orf94 | c.1552G>A p.G518R (on ENST00000488417 / NM_001134734.2; = p.G328R on NM_032884.5) | Missense Mutation (SNP) | VAF 68/249 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs768202401, COSV100974799; called by muse, mutect2, varscan2
- C21orf58 | c.571C>T p.P191S | Missense Mutation (SNP) | VAF 101/445 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.159); catalogued as COSV52450121; called by muse, mutect2, varscan2
- C22orf23 | c.470G>A p.R157Q | Missense Mutation (SNP) | VAF 56/245 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.26); catalogued as rs146578717; called by muse, varscan2
- C3 | c.2494G>A p.D832N | Missense Mutation (SNP) | VAF 71/344 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766179097; called by muse, mutect2, varscan2
- C7 | c.1205G>A p.R402Q | Missense Mutation (SNP) | VAF 55/268 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.973); catalogued as rs753530114, COSV57477052; called by muse, mutect2, varscan2
- C7 | c.2519C>T p.A840V | Missense Mutation (SNP) | VAF 54/240 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs761687811, COSV57472699; called by muse, mutect2, varscan2
- C8orf82 | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 218/513 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs538441298; called by muse, mutect2, varscan2
- CA10 | c.85C>T p.H29Y | Missense Mutation (SNP) | VAF 65/280 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.043); catalogued as rs138540087, COSV53352382; called by muse, mutect2, varscan2
- CABIN1 | c.4639C>T p.Q1547* | Nonsense Mutation (SNP) | VAF 46/231 reads (20%) | catalogued as rs1386949646; called by muse, mutect2, varscan2
- CACHD1 | c.3049C>T p.H1017Y | Missense Mutation (SNP) | VAF 29/257 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV51551612; called by muse, mutect2, varscan2
- CADPS2 | c.622G>A p.D208N | Missense Mutation (SNP) | VAF 50/262 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs746097190, COSV100462337; called by muse, mutect2, varscan2
- CALD1 | c.19C>T p.R7C | Missense Mutation (SNP) | VAF 53/232 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1230004440, COSV62654102; called by muse, mutect2, varscan2
- CASR | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 91/461 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.163); catalogued as rs201338034, COSV56137031; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC158 | c.1391C>T p.S464F | Missense Mutation (SNP) | VAF 66/256 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV66355394, COSV66357160; called by muse, mutect2, varscan2
- CD163 | c.3139C>T p.R1047C | Missense Mutation (SNP) | VAF 56/240 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.095); catalogued as rs746144692; called by muse, mutect2, varscan2
- CDHR1 | c.1882G>A p.E628K | Missense Mutation (SNP) | VAF 105/418 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as rs896814669; called by muse, mutect2, varscan2
- CDHR5 | c.214C>T p.R72W | Missense Mutation (SNP) | VAF 102/404 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs571458654, COSV51563914; called by muse, varscan2
- CELA1 | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 43/263 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs374315048; called by muse, mutect2, varscan2
- CGNL1 | c.1714G>A p.D572N | Missense Mutation (SNP) | VAF 33/174 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.27); catalogued as rs763987243; called by muse, mutect2, varscan2
- CHD4 | c.1273G>T p.G425W (on ENST00000357008 / NM_001363606.2; = p.G438W on NM_001273.5) | Missense Mutation (SNP) | VAF 73/363 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); catalogued as rs1315086872; called by muse, mutect2, varscan2
- CHD5 | c.3301C>T p.R1101W | Missense Mutation (SNP) | VAF 72/244 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs902336928; called by muse, mutect2, varscan2
- CHRM2 | c.1061G>A p.G354E | Missense Mutation (SNP) | VAF 85/346 reads (25%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.719); catalogued as COSV57771117; called by muse, mutect2, varscan2
- CNTNAP4 | c.2444C>T p.A815V | Missense Mutation (SNP) | VAF 58/270 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as rs377030540, COSV100273804; called by muse, mutect2, varscan2
- COL11A1 | c.3091G>A p.E1031K | Missense Mutation (SNP) | VAF 59/243 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.079); catalogued as COSV62196469; called by muse, mutect2, varscan2
- COL11A1 | c.1408G>A p.D470N | Missense Mutation (SNP) | VAF 69/281 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.16); catalogued as rs752749747, COSV100617349, COSV62180341; called by muse, mutect2, varscan2
- COL4A6 | c.3226G>A p.E1076K | Missense Mutation (SNP) | VAF 82/179 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.145); catalogued as rs1242571632, COSV57860672; called by muse, mutect2, varscan2
- CSHL1 | c.542C>T p.S181L (on ENST00000309894 / NM_022581.3; = p.S87L on NM_001318.4) | Missense Mutation (SNP) | VAF 112/456 reads (25%) | SIFT tolerated (0.72); PolyPhen benign (0.022); catalogued as rs773640867; called by muse, varscan2
- CSMD3 | c.920T>A p.L307* | Nonsense Mutation (SNP) | VAF 60/302 reads (20%) | catalogued as COSV99833245; called by muse, mutect2, varscan2
- DDX59 | c.1189C>T p.Q397* | Nonsense Mutation (SNP) | VAF 73/329 reads (22%) | catalogued as COSV58754139; called by muse, mutect2, varscan2
- DDX60L | c.1589C>T p.S530L | Missense Mutation (SNP) | VAF 74/325 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs761894325, COSV52716696; called by muse, mutect2, varscan2
- DEFB115 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 102/365 reads (28%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as COSV68723046; called by muse, mutect2, varscan2
- DEPDC5 | c.1574C>T p.S525F | Missense Mutation (SNP) | VAF 104/419 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV56696264; called by muse, mutect2, varscan2
- DIDO1 | c.4853C>T p.P1618L | Missense Mutation (SNP) | VAF 102/498 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs1156445980; called by muse, mutect2, varscan2
- DMP1 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 97/424 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs749046727, COSV56820181; called by muse, mutect2, varscan2
- DNAH6 | c.2308C>T p.P770S | Missense Mutation (SNP) | VAF 77/333 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.05); catalogued as COSV52862677; called by muse, mutect2, varscan2
- DNAH9 | c.5524C>T p.R1842C | Missense Mutation (SNP) | VAF 63/282 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs759051076; called by muse, mutect2, varscan2
- DNAJC18 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 73/341 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as rs1417070893; called by muse, mutect2, varscan2
- DOCK2 | c.4868C>T p.P1623L | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.049); catalogued as COSV56968142; called by muse, mutect2, varscan2
- DSCAM | c.4563G>A p.W1521* | Nonsense Mutation (SNP) | VAF 91/399 reads (23%) | catalogued as COSV101259695; called by muse, mutect2, varscan2
- DST | c.2086C>T p.R696W (on ENST00000361203 / NM_001374722.1; = p.R370W on NM_001723.6) | Missense Mutation (SNP) | VAF 80/305 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as rs775464446, COSV55023324; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EGFR | c.1049C>T p.S350F | Missense Mutation (SNP) | VAF 54/232 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV51775381; called by muse, mutect2, varscan2
- EMILIN2 | c.1066G>A p.D356N | Missense Mutation (SNP) | VAF 113/430 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as rs1401163922; called by muse, mutect2, varscan2
- ENPEP | c.1224G>A p.W408* | Nonsense Mutation (SNP) | VAF 61/269 reads (23%) | catalogued as rs756572616, COSV99036252; called by muse, mutect2, varscan2
- ERVV-2 | c.701C>T p.S234L | Missense Mutation (SNP) | VAF 86/366 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.855); catalogued as rs1299569175; called by muse, varscan2
- EZH2 | c.1732C>T p.R578* (on ENST00000460911 / NM_001203247.2; = p.R583* on NM_004456.5) | Nonsense Mutation (SNP) | VAF 77/344 reads (22%) | catalogued as COSV57449148; called by muse, mutect2, varscan2
- FAM71B | c.1316C>T p.P439L | Missense Mutation (SNP) | VAF 95/387 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.024); catalogued as rs1055104938, COSV57228630, COSV57228938; called by muse, mutect2, varscan2
- FAT3 | c.12019G>A p.E4007K | Missense Mutation (SNP) | VAF 69/237 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.982); catalogued as COSV53136268; called by muse, mutect2, varscan2
- FBXO39 | c.683C>T p.S228F | Missense Mutation (SNP) | VAF 70/308 reads (23%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs1445015921; called by muse, mutect2, varscan2
- GALNT15 | c.1856C>T p.P619L | Missense Mutation (SNP) | VAF 76/294 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs768652643, COSV60217895; called by muse, mutect2, varscan2
- GPANK1 | c.436C>T p.P146S | Missense Mutation (SNP) | VAF 170/666 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.817); catalogued as rs963936659, COSV63263782; called by muse, mutect2, varscan2
- GPAT3 | c.155G>A p.R52Q | Missense Mutation (SNP) | VAF 43/213 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.009); catalogued as COSV52355595; called by muse, mutect2, varscan2
- GRM3 | c.1390G>A p.G464R | Missense Mutation (SNP) | VAF 50/278 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs373913639; called by muse, varscan2
- GTF3C2 | c.358C>T p.P120S | Missense Mutation (SNP) | VAF 70/376 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs752194157; called by muse, mutect2, varscan2
- GUCA1C | c.520G>A p.D174N | Missense Mutation (SNP) | VAF 101/510 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as rs775107558, COSV53754730; called by muse, mutect2, varscan2
- IGFN1 | c.3596G>A p.G1199E (on ENST00000295591 / NM_001367841.1; = p.G3656E on NM_001164586.2) | Missense Mutation (SNP) | VAF 124/488 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0.186); catalogued as COSV55167607; called by muse, mutect2, varscan2
- IGHV4-28 | c.101C>T p.S34L | Missense Mutation (SNP) | VAF 82/288 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.139); catalogued as rs374397013; called by muse, mutect2, varscan2
- IGKV1D-16 | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 99/460 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.068); catalogued as rs774987960; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 91/210 reads (43%) | SIFT tolerated (0.41); PolyPhen benign (0.248); catalogued as rs1298370119, COSV61158149; called by muse, mutect2, varscan2
- INO80D | c.2744C>T p.S915F | Missense Mutation (SNP) | VAF 88/381 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV68958273; called by muse, mutect2, varscan2
- INPP5D | c.452G>A p.R151Q (on ENST00000445964 / NM_001017915.3; = p.R150Q on NM_005541.5) | Missense Mutation (SNP) | VAF 94/346 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.035); catalogued as rs758777451, COSV64041218; called by muse, mutect2
- KERA | c.967C>T p.R323C | Missense Mutation (SNP) | VAF 71/286 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs148063461; called by muse, mutect2, varscan2
- LRRK2 | c.5827C>T p.R1943W | Missense Mutation (SNP) | VAF 89/350 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs756387719, COSV54163575; called by muse, mutect2, varscan2
- LRTM2 | c.1100C>T p.S367F | Missense Mutation (SNP) | VAF 65/259 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV54564553; called by muse, mutect2, varscan2
- MAGEB6 | c.416C>T p.S139F | Missense Mutation (SNP) | VAF 125/262 reads (48%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.987); catalogued as rs774306818, COSV66871883, COSV66872776; called by muse, mutect2, varscan2
- MAGEC1 | c.2131C>T p.P711S | Missense Mutation (SNP) | VAF 133/247 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); catalogued as rs751959644, COSV53568902; called by muse, mutect2, varscan2
- MAGEE2 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 105/239 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as rs765806534; called by muse, mutect2, varscan2
- MAML3 | c.3410A>G p.N1137S | Missense Mutation (SNP) | VAF 53/202 reads (26%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.97); catalogued as COSV101558536; called by muse, mutect2, varscan2
- MGAM | c.3406G>A p.E1136K | Missense Mutation (SNP) | VAF 102/485 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866353991, COSV72074697; called by muse, mutect2, varscan2
- MORC2 | c.547G>A p.E183K (on ENST00000397641 / NM_001303256.3; = p.E121K on NM_014941.3) | Missense Mutation (SNP) | VAF 80/328 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as rs892112351; called by muse, mutect2, varscan2
- MPO | c.2234C>T p.S745F | Missense Mutation (SNP) | VAF 43/194 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV51861838; called by muse, mutect2, varscan2
- MSR1 | c.980G>A p.G327E | Missense Mutation (SNP) | VAF 55/229 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV50523234; called by muse, mutect2, varscan2
- MYF5 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 94/364 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as COSV57354247; called by muse, mutect2, varscan2
- MYL4 | c.371C>T p.S124F | Missense Mutation (SNP) | VAF 68/256 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as rs1567749846; called by muse, mutect2, varscan2
- MYO15A | c.4018G>A p.E1340K | Missense Mutation (SNP) | VAF 73/293 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV52762178, COSV99234972; called by muse, mutect2, varscan2
- MYO7A | c.470G>T p.S157I | Missense Mutation (SNP) | VAF 60/234 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM061137; called by muse, mutect2
- MYOCD | c.2236G>A p.E746K | Missense Mutation (SNP) | VAF 63/266 reads (24%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.998); catalogued as rs897626201, COSV100591337, COSV58506726; called by muse, mutect2, varscan2
- NACA2 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 91/417 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as rs61739272; called by muse, mutect2, varscan2
- NDST4 | c.2491G>A p.D831N | Missense Mutation (SNP) | VAF 36/200 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.117); catalogued as COSV52109110, COSV52113122; called by muse, mutect2, varscan2
- NEK10 | c.41C>T p.S14L | Missense Mutation (SNP) | VAF 33/269 reads (12%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); catalogued as COSV58281065; called by muse, mutect2, varscan2
- NES | c.4462G>T p.E1488* | Nonsense Mutation (SNP) | VAF 96/375 reads (26%) | catalogued as COSV63962932; called by muse, mutect2, varscan2
- NLRP4 | c.1618G>A p.E540K | Missense Mutation (SNP) | VAF 80/382 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0.014); catalogued as COSV56707442; called by muse, mutect2, varscan2
- NOMO1 | c.1033C>T p.P345S | Missense Mutation (SNP) | VAF 38/338 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV99814504; called by muse, mutect2, varscan2
- NR0B2 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 110/351 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0.146); catalogued as COSV99575073; called by muse, mutect2, varscan2
- NR2F1 | c.232G>A p.G78S | Missense Mutation (SNP) | VAF 57/256 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs1255702001; called by muse, mutect2, varscan2
- OCIAD2 | c.425G>A p.G142E | Missense Mutation (SNP) | VAF 83/338 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs768258880, COSV56717096; called by muse, mutect2, varscan2
- OOEP | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 100/396 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.356); catalogued as rs868133344, COSV64859087; called by muse, mutect2, varscan2
- OR2G2 | c.332G>A p.G111E | Missense Mutation (SNP) | VAF 86/319 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100189780, COSV104410690, COSV60741708; called by muse, mutect2, varscan2
- OR2G3 | c.23C>T p.S8F | Missense Mutation (SNP) | VAF 44/185 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV100180795, COSV60680774; called by muse, mutect2, varscan2
- OR2G3 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 61/244 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs904551280, COSV60681053; called by muse, mutect2, varscan2
- OR4Q2 | c.281C>T p.S94F | Missense Mutation (SNP) | VAF 70/208 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.228); catalogued as rs1190649339; called by muse, mutect2, varscan2
- OR5B17 | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 72/322 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs868743937, COSV62159822; called by muse, mutect2, varscan2
- OR5H15 | c.463C>T p.H155Y | Missense Mutation (SNP) | VAF 80/508 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.4); catalogued as COSV62947850; called by muse, mutect2
- OR6K2 | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 77/327 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs761748992, COSV62743302; called by muse, mutect2, varscan2
- PADI4 | c.1138C>T p.P380S | Missense Mutation (SNP) | VAF 18/230 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100966771; called by muse, mutect2
- PARP4 | c.4301C>T p.S1434F | Missense Mutation (SNP) | VAF 72/364 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV67961583; called by muse, mutect2, varscan2
- PCDHA1 | c.2203G>A p.G735S | Missense Mutation (SNP) | VAF 82/391 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.517); catalogued as rs782082535, COSV65375789; called by mutect2, varscan2
- PCDHA13 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 86/321 reads (27%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.098); catalogued as rs782514861; called by muse, mutect2, varscan2
- PCLO | c.12995C>T p.S4332L | Missense Mutation (SNP) | VAF 62/312 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.121); catalogued as COSV61629887; called by muse, mutect2, varscan2
- PDE1A | c.1421G>A p.R474Q | Missense Mutation (SNP) | VAF 60/250 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs757725272, COSV59542273; called by muse, varscan2
- PEG3 | c.2119C>T p.H707Y | Missense Mutation (SNP) | VAF 93/408 reads (23%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.858); catalogued as rs775898856, COSV55627247; called by muse, mutect2, varscan2
- PHYHD1 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 48/174 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as rs147855994; called by muse, mutect2, varscan2
- PIK3C2G | c.2902C>T p.R968C (on ENST00000676171; = p.R927C on NM_004570.5) | Missense Mutation (SNP) | VAF 44/192 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368805708; called by muse, mutect2, varscan2
- PITPNM2 | c.1116G>A p.M372I | Missense Mutation (SNP) | VAF 63/318 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.19); catalogued as rs946253366; called by muse, mutect2, varscan2
- PITRM1 | c.1589C>G p.S530C | Missense Mutation (SNP) | VAF 63/275 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56538023; called by muse, mutect2, varscan2
- PLEC | c.4039C>T p.R1347C (on ENST00000322810 / NM_201380.4; = p.R1237C on NM_000445.5) | Missense Mutation (SNP) | VAF 191/517 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); catalogued as rs782365536, COSV59695322; called by muse, mutect2, varscan2
- PLEKHS1 | c.638G>A p.R213Q (on ENST00000369310 / NM_182601.1; = p.R219Q on NM_024889.5) | Missense Mutation (SNP) | VAF 60/230 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.372); catalogued as rs267602368, COSV63054937; called by muse, mutect2, varscan2
- PTDSS2 | c.904C>T p.R302C | Missense Mutation (SNP) | VAF 114/419 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.733); catalogued as rs1295689603, COSV57278441; called by muse, mutect2, varscan2
- PTPRD | c.2242C>T p.Q748* | Nonsense Mutation (SNP) | VAF 89/331 reads (27%) | catalogued as COSV100642539; called by muse, mutect2, varscan2
- PTTG2 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 58/247 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs1355430381; called by muse, mutect2, varscan2
- RAI14 | c.1525G>A p.G509S | Missense Mutation (SNP) | VAF 100/369 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.9); catalogued as rs777066453; called by muse, mutect2, varscan2
- RGS11 | c.690C>T p.I230= (on ENST00000397770 / NM_183337.3; = p.I209= on NM_003834.3 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 94/493 reads (19%) | catalogued as rs762247831, COSV51451523; called by muse, mutect2, varscan2
- RHOB | c.148G>A p.G50S | Missense Mutation (SNP) | VAF 98/399 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.044); catalogued as rs1347623585; called by muse, mutect2, varscan2
- RHOB | c.149G>A p.G50D | Missense Mutation (SNP) | VAF 100/404 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as rs1341957519; called by muse, mutect2, varscan2
- RNF220 | c.767C>T p.S256F | Missense Mutation (SNP) | VAF 40/228 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.052); catalogued as COSV100699128; called by muse, mutect2, varscan2
- RUNDC3B | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 94/374 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.866); catalogued as rs1173051243, COSV56692938; called by muse, varscan2
- SFI1 | c.650G>A p.R217Q | Missense Mutation (SNP) | VAF 49/202 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs766247561; called by muse, mutect2, varscan2
- SH3GL3 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 63/248 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.633); catalogued as COSV61061661; called by muse, mutect2, varscan2
- SHD | c.910G>A p.G304R | Missense Mutation (SNP) | VAF 76/300 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.174); catalogued as rs373893063; called by muse, varscan2
- SIGLEC7 | c.995C>T p.S332F | Missense Mutation (SNP) | VAF 71/261 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.461); catalogued as COSV58315928; called by muse, mutect2, varscan2
- SIRPD | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 160/436 reads (37%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.006); catalogued as COSV99061190; called by muse, mutect2, varscan2
- SLC15A1 | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 45/233 reads (19%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as COSV64732368; called by muse, mutect2, varscan2
- SLC27A4 | c.1312C>T p.P438S | Missense Mutation (SNP) | VAF 48/170 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.14); catalogued as COSV55961076; called by muse, mutect2, varscan2
- SLC9C2 | c.599G>A p.G200E | Missense Mutation (SNP) | VAF 29/203 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.046); catalogued as rs267598172, COSV62945331; called by muse, mutect2, varscan2
- ST14 | c.1007G>A p.R336K | Missense Mutation (SNP) | VAF 46/143 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1048179152; called by muse, mutect2, varscan2
- SYCP1 | c.2465G>A p.R822Q | Missense Mutation (SNP) | VAF 57/591 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs765636850; called by muse, mutect2, varscan2
- TFPI | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 63/279 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.042); catalogued as rs868175148, COSV99259446; called by muse, mutect2, varscan2
- TMEM132D | c.1923G>A p.Q641= | Splice Region (SNP) | VAF 36/172 reads (21%) | catalogued as rs1201674481, COSV67160836; called by muse, mutect2, varscan2
- TMEM132D | c.406G>A p.D136N | Missense Mutation (SNP) | VAF 83/412 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as COSV70611429; called by muse, mutect2, varscan2
- TMPRSS11A | c.962G>A p.G321E | Missense Mutation (SNP) | VAF 61/214 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866681652; called by muse, mutect2, varscan2
- TP53BP1 | c.2501C>T p.S834F | Missense Mutation (SNP) | VAF 54/245 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV55507044; called by muse, mutect2, varscan2
- TRANK1 | c.7372G>A p.D2458N | Missense Mutation (SNP) | VAF 57/263 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.299); catalogued as COSV100083052; called by muse, mutect2, varscan2
- TRBV7-1 | c.194C>T p.P65L | Missense Mutation (SNP) | VAF 79/316 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs771870239; called by muse, mutect2, varscan2
- TRIM7 | c.1532C>T p.P511L | Missense Mutation (SNP) | VAF 47/261 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV51240910; called by muse, mutect2, varscan2
- TTN | c.22391G>A p.G7464E (on ENST00000591111; = p.G6537E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 95/320 reads (30%) | PolyPhen benign (0.364); catalogued as rs868631561, COSV60441218; called by muse, mutect2, varscan2
- TTN | c.3356G>A p.G1119D (on ENST00000591111; = p.G1073D on NM_003319.4) | Missense Mutation (SNP) | VAF 55/273 reads (20%) | PolyPhen probably damaging (1); catalogued as COSV60366594; called by muse, mutect2, varscan2
- UGT2B15 | c.1024G>T p.G342C | Missense Mutation (SNP) | VAF 55/346 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779446832; called by mutect2, varscan2
- USP28 | c.1165C>T p.P389S | Missense Mutation (SNP) | VAF 37/142 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.893); catalogued as COSV50177361; called by muse, mutect2, varscan2
- VGLL1 | c.598G>A p.G200R | Missense Mutation (SNP) | VAF 86/209 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.1); catalogued as rs374712904; called by muse, mutect2, varscan2
- WDR72 | c.2665G>A p.E889K | Missense Mutation (SNP) | VAF 85/296 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs921714846, COSV100854286, COSV64741937; called by muse, mutect2, varscan2
- XDH | c.2719C>T p.P907S | Missense Mutation (SNP) | VAF 105/455 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.061); catalogued as rs1211886664, COSV65146673; called by muse, mutect2, varscan2
- XYLT1 | c.2723C>T p.S908L | Missense Mutation (SNP) | VAF 209/558 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.288); catalogued as rs748327396, COSV54494298; called by muse, mutect2, varscan2
- ZFHX4 | c.506C>T p.S169F | Missense Mutation (SNP) | VAF 125/307 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV51492225, COSV99070790; called by muse, mutect2, varscan2
- ZNF101 | c.259C>T p.P87S | Missense Mutation (SNP) | VAF 77/303 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.048); catalogued as rs750915472, COSV100543566; called by muse, mutect2, varscan2
- ZNF574 | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 65/324 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs759651572, COSV55902269; called by muse, mutect2, varscan2
- ZNF679 | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 74/330 reads (22%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs777415929, COSV55380408; called by muse, mutect2, varscan2
- ZXDC | c.1661C>T p.P554L | Missense Mutation (SNP) | VAF 71/391 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); catalogued as COSV100306346; called by muse, mutect2, varscan2
- ACSS2 | c.1292C>T p.S431F | Missense Mutation (SNP) | VAF 56/404 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- ACTR5 | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 59/327 reads (18%) | SIFT tolerated (0.99); PolyPhen benign (0); called by muse, mutect2
- ADAMTS16 | c.1333G>A p.G445R | Missense Mutation (SNP) | VAF 48/188 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ADCY2 | c.875T>C p.L292S | Missense Mutation (SNP) | VAF 74/221 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRB1 | c.2308G>A p.V770I | Missense Mutation (SNP) | VAF 32/225 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- AKR1B15 | c.262C>T p.Q88* | Nonsense Mutation (SNP) | VAF 78/342 reads (23%) | called by muse, mutect2, varscan2
- ANKRD34C | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 83/294 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ANKUB1 | c.308C>T p.S103F | Missense Mutation (SNP) | VAF 66/402 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- AP3B1 | c.3266C>T p.P1089L | Missense Mutation (SNP) | VAF 62/272 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- ARC | c.571G>A p.A191T | Missense Mutation (SNP) | VAF 142/696 reads (20%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ARID5B | c.632G>A p.G211E | Missense Mutation (SNP) | VAF 65/321 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARIH1 | c.1444C>T p.L482F | Missense Mutation (SNP) | VAF 61/273 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ATP8B2 | c.3269C>T p.A1090V (on ENST00000672630; = p.A1057V on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/215 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- C1R | c.344G>A p.G115E (on ENST00000536053 / NM_001354346.2; = p.G101E on NM_001733.7) | Missense Mutation (SNP) | VAF 92/350 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- C5orf46 | c.38G>A p.G13E | Missense Mutation (SNP) | VAF 53/223 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CABLES2 | c.1339G>A p.G447R | Missense Mutation (SNP) | VAF 67/434 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- CACNB2 | c.1502A>C p.D501A (on ENST00000324631 / NM_201596.3; = p.D446A on NM_000724.4) | Missense Mutation (SNP) | VAF 42/176 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- CCDC112 | c.589C>T p.P197S | Missense Mutation (SNP) | VAF 54/276 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- CCDC77 | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 69/341 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CD36 | c.503C>T p.S168F | Missense Mutation (SNP) | VAF 61/268 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- CDC42BPG | c.1882C>T p.P628S | Missense Mutation (SNP) | VAF 81/415 reads (20%) | SIFT tolerated (0.68); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CEP112 | c.2269G>A p.E757K | Missense Mutation (SNP) | VAF 82/325 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- CFAP57 | c.1235C>T p.S412F | Missense Mutation (SNP) | VAF 56/286 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- CLCN1 | c.2721G>A p.W907* | Nonsense Mutation (SNP) | VAF 108/458 reads (24%) | called by muse, mutect2, varscan2
- COL13A1 | c.1604C>T p.P535L (on ENST00000398978 / NM_001130103.2; = p.P478L on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 80/356 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- COL1A2 | c.3910G>A p.G1304S | Missense Mutation (SNP) | VAF 69/294 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL20A1 | c.994G>A p.D332N | Missense Mutation (SNP) | VAF 216/560 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CPB2 | c.986A>C p.D329A | Missense Mutation (SNP) | VAF 54/186 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, varscan2
- CSMD3 | c.8144A>G p.Y2715C | Missense Mutation (SNP) | VAF 155/380 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DCN | c.592G>A p.G198R | Missense Mutation (SNP) | VAF 51/276 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DDX60L | c.885A>C p.R295S | Missense Mutation (SNP) | VAF 79/310 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- DMPK | c.1421C>T p.A474V | Missense Mutation (SNP) | VAF 79/389 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- DSCAM | c.5599G>A p.G1867R | Missense Mutation (SNP) | VAF 79/341 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DSG2 | c.153G>A p.W51* | Nonsense Mutation (SNP) | VAF 70/336 reads (21%) | called by muse, mutect2, varscan2
- DSG3 | c.2276C>T p.S759F | Missense Mutation (SNP) | VAF 89/399 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- EFCAB8 | c.1857-1G>A p.X619_splice | Splice Site (SNP) | VAF 36/242 reads (15%) | called by muse, mutect2, varscan2
- EFEMP1 | c.332G>A p.G111E | Missense Mutation (SNP) | VAF 77/373 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- EGFR | c.2896A>C p.I966L | Missense Mutation (SNP) | VAF 85/303 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- ELAPOR2 | c.2764G>A p.E922K (on ENST00000450689 / NM_001142749.3; = p.E755K on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 92/322 reads (29%) | SIFT tolerated (0.74); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- ELOA3C | c.635G>A p.G212D | Missense Mutation (SNP) | VAF 84/3476 reads (2%) | SIFT tolerated (0.2); PolyPhen benign (0.144); called by muse, mutect2
- ENOX2 | c.220C>T p.P74S (on ENST00000338144 / NM_001382520.1; = p.P45S on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 71/163 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- EPHB2 | c.2953G>A p.E985K (on ENST00000400191 / NM_001309193.2; = p.E986K on NM_004442.7) | Missense Mutation (SNP) | VAF 38/253 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ETV3L | c.539G>A p.G180E | Missense Mutation (SNP) | VAF 64/250 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- FAM160A2 | c.2150C>T p.P717L (on ENST00000449352 / NM_001098794.2; = p.P731L on NM_032127.4) | Missense Mutation (SNP) | VAF 109/437 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- FAM178B | c.1019C>T p.S340F | Missense Mutation (SNP) | VAF 44/197 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FER1L6 | c.359G>A p.G120E | Missense Mutation (SNP) | VAF 94/249 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FOLH1 | c.121T>A p.W41R | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- FREM3 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 89/333 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- GLIS3 | c.194G>A p.G65E | Missense Mutation (SNP) | VAF 98/334 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- GNAO1 | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 82/376 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPR148 | c.1040C>T p.S347F | Missense Mutation (SNP) | VAF 52/237 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HABP2 | c.1303T>G p.C435G | Missense Mutation (SNP) | VAF 92/393 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HOMER1 | c.155G>A p.G52D | Missense Mutation (SNP) | VAF 51/179 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HPGDS | c.249G>A p.M83I | Missense Mutation (SNP) | VAF 58/251 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HS3ST1 | c.806C>T p.S269F | Missense Mutation (SNP) | VAF 70/316 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HSFX1 | c.94C>G p.Q32E | Missense Mutation (SNP) | VAF 84/418 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- IFT122 | c.542C>T p.S181F | Missense Mutation (SNP) | VAF 94/264 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- IFT88 | c.355G>A p.G119S (on ENST00000319980 / NM_001318493.2; = p.G110S on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/234 reads (16%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- IGLV2-23 | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 92/393 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.397); called by muse, mutect2, varscan2
- IL13 | c.73C>T p.L25F | Missense Mutation (SNP) | VAF 105/440 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- IMPG1 | c.682T>G p.F228V | Missense Mutation (SNP) | VAF 66/276 reads (24%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITGB8 | c.593C>T p.P198L | Missense Mutation (SNP) | VAF 41/200 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITPR1 | c.5806C>T p.P1936S (on ENST00000354582; = p.P1881S on NM_002222.7) | Missense Mutation (SNP) | VAF 68/451 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- KDELR3 | c.604+1G>A p.X202_splice | Splice Site (SNP) | VAF 85/321 reads (26%) | called by muse, mutect2, varscan2
- KIF26B | c.725C>T p.P242L | Missense Mutation (SNP) | VAF 135/584 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- KLF10 | c.1197C>G p.F399L | Missense Mutation (SNP) | VAF 73/322 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KLHDC7A | c.1276C>T p.P426S | Missense Mutation (SNP) | VAF 96/361 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- LIMCH1 | c.1113G>A p.W371* | Nonsense Mutation (SNP) | VAF 76/266 reads (29%) | called by muse, mutect2, varscan2
- LIMD1 | c.355_357del p.T119del | In Frame Del (DEL) | VAF 42/356 reads (12%) | called by pindel, varscan2
- LRFN2 | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 75/410 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); called by muse, varscan2
- LRFN2 | c.119C>T p.S40F | Missense Mutation (SNP) | VAF 81/388 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.052); called by muse, varscan2
- LRFN2 | c.118T>G p.S40A | Missense Mutation (SNP) | VAF 82/388 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, varscan2
- LTK | c.451G>A p.G151S | Missense Mutation (SNP) | VAF 79/351 reads (23%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MAP1A | c.8389C>T p.P2797S | Missense Mutation (SNP) | VAF 64/274 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- MAP3K21 | c.1630C>T p.P544S | Missense Mutation (SNP) | VAF 101/429 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- MATK | c.376A>C p.K126Q (on ENST00000310132 / NM_139355.3; = p.K127Q on NM_002378.4) | Missense Mutation (SNP) | VAF 65/340 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- MCHR1 | c.1055G>A p.S352N | Missense Mutation (SNP) | VAF 105/392 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MCTP1 | c.836G>A p.G279E | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- MGA | c.3922A>C p.S1308R | Missense Mutation (SNP) | VAF 46/219 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- MUC2 | c.1798G>A p.G600S | Missense Mutation (SNP) | VAF 61/280 reads (22%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- MYH10 | c.2713G>A p.E905K | Missense Mutation (SNP) | VAF 57/282 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NIN | c.4705C>T p.Q1569* (on ENST00000382041 / NM_182946.1; = p.Q856* on NM_016350.4) | Nonsense Mutation (SNP) | VAF 40/161 reads (25%) | called by muse, mutect2, varscan2
- OGFR | c.1144_1145del p.S382Qfs*81 | Frame Shift Del (DEL) | VAF 96/606 reads (16%) | called by pindel, varscan2
- OOSP2 | c.407C>T p.P136L | Missense Mutation (SNP) | VAF 47/206 reads (23%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- OR51I2 | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 92/351 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR5G3 | c.483T>A p.F161L | Missense Mutation (SNP) | VAF 53/259 reads (20%) | SIFT tolerated, low confidence (0.09); called by muse, mutect2, varscan2
- OSBPL10 | c.739C>T p.Q247* | Nonsense Mutation (SNP) | VAF 25/232 reads (11%) | called by muse, mutect2
- P3H2 | c.1850G>A p.G617E | Missense Mutation (SNP) | VAF 105/331 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PAF1 | c.566C>T p.S189L | Missense Mutation (SNP) | VAF 69/240 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.415); called by muse, mutect2, varscan2
- PAGE2B | c.32C>T p.S11F | Missense Mutation (SNP) | VAF 93/179 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PARP15 | c.245C>T p.S82L | Missense Mutation (SNP) | VAF 56/304 reads (18%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PCDH12 | c.1922G>A p.G641E | Missense Mutation (SNP) | VAF 93/360 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PCNT | c.4738C>T p.Q1580* | Nonsense Mutation (SNP) | VAF 80/356 reads (22%) | called by muse, mutect2, varscan2
- PIEZO2 | c.4841A>T p.K1614I | Missense Mutation (SNP) | VAF 77/262 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PIP4K2C | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 57/277 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PITPNM2 | c.1117G>A p.D373N | Missense Mutation (SNP) | VAF 62/316 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- PLEKHO1 | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 102/381 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLSCR5 | c.710G>A p.G237E | Missense Mutation (SNP) | VAF 73/416 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- POM121C | c.2222C>T p.T741I (on ENST00000607367; = p.T499I on NM_001099415.3) | Missense Mutation (SNP) | VAF 93/273 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- PRSS56 | c.1739G>A p.G580E | Missense Mutation (SNP) | VAF 111/472 reads (24%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- PSG8 | c.1117C>T p.Q373* | Nonsense Mutation (SNP) | VAF 88/453 reads (19%) | called by muse, mutect2, varscan2
- PTPRK | c.1732G>A p.G578S | Missense Mutation (SNP) | VAF 79/286 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPRM | c.2600C>T p.A867V | Missense Mutation (SNP) | VAF 85/332 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPRQ | c.4144C>T p.P1382S (on ENST00000616559; = p.P1340S on NM_001145026.2) | Missense Mutation (SNP) | VAF 37/196 reads (19%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- REEP3 | c.572G>A p.G191E | Missense Mutation (SNP) | VAF 44/194 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0.003); called by muse, varscan2
- RIF1 | c.2522T>A p.V841E | Missense Mutation (SNP) | VAF 54/255 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- RIMBP2 | c.1688C>T p.T563I | Missense Mutation (SNP) | VAF 103/420 reads (25%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- RNF8 | c.1168C>T p.L390F | Missense Mutation (SNP) | VAF 44/231 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ROBO1 | c.1168C>T p.Q390* | Nonsense Mutation (SNP) | VAF 19/139 reads (14%) | called by muse, mutect2, varscan2
- RS1 | c.244A>C p.T82P | Missense Mutation (SNP) | VAF 102/214 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- SEC24B | c.3089C>T p.S1030F | Missense Mutation (SNP) | VAF 38/176 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SHC2 | c.1121C>T p.P374L | Missense Mutation (SNP) | VAF 45/256 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- SHD | c.911G>A p.G304E | Missense Mutation (SNP) | VAF 78/308 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.484); called by muse, varscan2
- SLC12A1 | c.2054T>A p.I685N | Missense Mutation (SNP) | VAF 65/285 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); called by mutect2, varscan2
- SLC17A2 | c.1006C>T p.L336F | Missense Mutation (SNP) | VAF 106/374 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- SLC32A1 | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 109/572 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SP110 | c.1093C>T p.Q365* | Nonsense Mutation (SNP) | VAF 57/286 reads (20%) | called by muse, mutect2, varscan2
- ST6GALNAC2 | c.574A>T p.T192S | Missense Mutation (SNP) | VAF 52/311 reads (17%) | PolyPhen benign (0.054); called by muse, mutect2, varscan2
- STEAP3 | c.1340C>T p.A447V | Missense Mutation (SNP) | VAF 107/397 reads (27%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYNRG | c.2884C>T p.P962S | Missense Mutation (SNP) | VAF 117/447 reads (26%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TBCD | c.2278T>C p.Y760H | Missense Mutation (SNP) | VAF 72/342 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- THBS1 | c.947C>T p.P316L | Missense Mutation (SNP) | VAF 64/290 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- TLN2 | c.5905C>T p.L1969F | Missense Mutation (SNP) | VAF 55/271 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TOM1 | c.682A>C p.S228R | Missense Mutation (SNP) | VAF 59/268 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TRMT2B | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 74/166 reads (45%) | SIFT tolerated (0.74); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TTC6 | c.947C>T p.S316F | Missense Mutation (SNP) | VAF 52/139 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- TTN | c.49561G>A p.D16521N (on ENST00000591111; = p.D9097N on NM_003319.4) | Missense Mutation (SNP) | VAF 88/354 reads (25%) | PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- UBC | c.476C>T p.T159I | Missense Mutation (SNP) | VAF 106/461 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ULK2 | c.1558C>T p.L520F | Missense Mutation (SNP) | VAF 56/224 reads (25%) | SIFT tolerated (0.62); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- UNC80 | c.6282G>C p.K2094N | Missense Mutation (SNP) | VAF 46/224 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- USH1C | c.1213G>A p.D405N | Missense Mutation (SNP) | VAF 54/252 reads (21%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, varscan2
- USP17L2 | c.49T>A p.F17I | Missense Mutation (SNP) | VAF 92/288 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.293); called by muse, mutect2
- VWA2 | c.1387G>A p.G463S | Missense Mutation (SNP) | VAF 107/447 reads (24%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- VWA5B2 | c.3556G>T p.E1186* | Nonsense Mutation (SNP) | VAF 110/622 reads (18%) | called by muse, mutect2
- WDR27 | c.2024C>T p.S675F | Missense Mutation (SNP) | VAF 59/205 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- ZBTB40 | c.2741C>T p.T914I | Missense Mutation (SNP) | VAF 79/309 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.538); called by muse, mutect2, varscan2
- ZC3H6 | c.3493C>T p.P1165S | Missense Mutation (SNP) | VAF 74/354 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- ZC3H6 | c.3494C>T p.P1165L | Missense Mutation (SNP) | VAF 74/349 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZMYND11 | c.609G>A p.E203= | Splice Region (SNP) | VAF 52/201 reads (26%) | called by muse, mutect2, varscan2
- ZNF33A | c.2044C>T p.H682Y (on ENST00000458705 / NM_006974.3; = p.H683Y on NM_006954.2) | Missense Mutation (SNP) | VAF 71/338 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF395 | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 91/414 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF398 | c.1345C>T p.H449Y (on ENST00000475153 / NM_170686.3; = p.H278Y on NM_020781.4) | Missense Mutation (SNP) | VAF 102/457 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF461 | c.47C>T p.S16F | Missense Mutation (SNP) | VAF 74/312 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- ZNF664 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 56/275 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- ZNF728 | c.1756C>T p.H586Y | Missense Mutation (SNP) | VAF 62/261 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF776 | c.1333G>A p.G445S | Missense Mutation (SNP) | VAF 101/409 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZSCAN20 | c.242G>C p.R81T | Missense Mutation (SNP) | VAF 36/418 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ACE | c.1323C>T p.D441= | Silent (SNP) | VAF 47/223 reads (21%) | catalogued as rs773913073; called by muse, mutect2, varscan2
- ADAM2 | c.2139G>A p.R713= | Silent (SNP) | VAF 52/224 reads (23%) | catalogued as rs267601919, COSV55858842; called by muse, mutect2, varscan2
- ADAM7 | c.1014G>A p.G338= | Silent (SNP) | VAF 100/318 reads (31%) | called by muse, mutect2, varscan2
- ADAMTS7 | c.1728C>T p.Y576= | Silent (SNP) | VAF 82/332 reads (25%) | catalogued as rs1387736193; called by muse, varscan2
- AGBL2 | c.2064C>T p.I688= | Silent (SNP) | VAF 62/287 reads (22%) | catalogued as COSV54090233; called by muse, mutect2, varscan2
- ANO4 | c.606C>T p.I202= (on ENST00000392977 / NM_001286615.2; = p.I167= on NM_178826.4) | Silent (SNP) | VAF 36/157 reads (23%) | catalogued as rs566155639, COSV54587521; called by muse, mutect2, varscan2
- ANO7 | c.2586C>T p.F862= (on ENST00000274979; = p.F808= on NM_001370694.2) | Silent (SNP) | VAF 64/243 reads (26%) | called by muse, mutect2, varscan2
- AP1M1 | c.153C>T p.A51= | Silent (SNP) | VAF 82/372 reads (22%) | called by muse, mutect2, varscan2
- BCAS1 | c.1503G>A p.K501= | Silent (SNP) | VAF 171/462 reads (37%) | called by muse, mutect2, varscan2
- BCO2 | c.1038G>A p.G346= | Silent (SNP) | VAF 38/150 reads (25%) | called by muse, mutect2, varscan2
- C6 | c.945G>A p.R315= | Silent (SNP) | VAF 29/158 reads (18%) | catalogued as COSV54715199; called by muse, mutect2, varscan2
- C6orf163 | c.732G>A p.Q244= | Silent (SNP) | VAF 89/381 reads (23%) | called by muse, mutect2, varscan2
- CASC3 | c.1209C>T p.S403= | Silent (SNP) | VAF 94/382 reads (25%) | catalogued as COSV99229427; called by muse, mutect2, varscan2
- CASTOR2 | c.693C>T p.F231= | Silent (SNP) | VAF 101/400 reads (25%) | catalogued as COSV62478056; called by muse, mutect2, varscan2
- CCKAR | c.696C>T p.I232= | Silent (SNP) | VAF 54/262 reads (21%) | called by muse, mutect2, varscan2
- CES5A | c.1335G>A p.T445= | Silent (SNP) | VAF 92/384 reads (24%) | catalogued as rs747962253, COSV51867987, COSV51871652; called by muse, mutect2, varscan2
- CFAP47 | c.8769C>T p.F2923= | Silent (SNP) | VAF 62/126 reads (49%) | catalogued as rs376579195, COSV66217190, COSV66220583; called by muse, mutect2, varscan2
- CHD6 | c.1368G>A p.K456= | Silent (SNP) | VAF 64/342 reads (19%) | called by muse, mutect2, varscan2
- CKM | c.279C>T p.I93= | Silent (SNP) | VAF 86/314 reads (27%) | catalogued as COSV99675677; called by muse, mutect2, varscan2
- CLEC16A | c.2862C>T p.I954= | Silent (SNP) | VAF 64/367 reads (17%) | catalogued as rs766801240, COSV55490851; called by muse, mutect2, varscan2
- CNGA2 | c.1566C>T p.I522= | Silent (SNP) | VAF 84/196 reads (43%) | called by muse, mutect2, varscan2
- COL6A6 | c.3324C>T p.V1108= | Silent (SNP) | VAF 214/552 reads (39%) | called by muse, mutect2, varscan2
- COMP | c.1674G>A p.R558= | Silent (SNP) | VAF 93/326 reads (29%) | catalogued as rs774980274; called by muse, mutect2, varscan2
- CPXCR1 | c.345G>A p.G115= | Silent (SNP) | VAF 116/236 reads (49%) | catalogued as COSV52163907; called by muse, mutect2, varscan2
- CSRNP1 | c.840C>T p.G280= | Silent (SNP) | VAF 33/288 reads (11%) | called by muse, mutect2, varscan2
- CXorf58 | c.768G>A p.R256= | Silent (SNP) | VAF 82/160 reads (51%) | called by muse, mutect2, varscan2
- DCC | c.2868G>A p.R956= | Silent (SNP) | VAF 79/279 reads (28%) | catalogued as rs376346520, COSV59145727; called by muse, mutect2, varscan2
- DDX55 | c.124C>T p.L42= | Silent (SNP) | VAF 68/231 reads (29%) | catalogued as rs373692972; called by muse, mutect2, varscan2
- DNAH11 | c.7485C>T p.F2495= | Silent (SNP) | VAF 75/315 reads (24%) | catalogued as rs771739801, COSV60952688; called by muse, mutect2, varscan2
- DNTT | c.1491G>A p.L497= | Silent (SNP) | VAF 51/226 reads (23%) | catalogued as rs1441308237; called by muse, mutect2, varscan2
- DUSP8 | c.1428C>T p.F476= | Silent (SNP) | VAF 20/100 reads (20%) | called by muse, mutect2, varscan2
- DYRK3 | c.1140C>T p.I380= | Silent (SNP) | VAF 83/341 reads (24%) | called by muse, mutect2, varscan2
- ENPP3 | c.219G>A p.V73= | Silent (SNP) | VAF 81/239 reads (34%) | called by muse, mutect2, varscan2
- ERICH3 | c.3183G>A p.R1061= | Silent (SNP) | VAF 87/352 reads (25%) | catalogued as rs755318663, COSV58610729; called by muse, mutect2
- EXOC1L | c.453C>T p.V151= | Silent (SNP) | VAF 59/273 reads (22%) | called by muse, mutect2, varscan2
- EXOC6 | c.1314C>T p.D438= | Silent (SNP) | VAF 42/190 reads (22%) | catalogued as rs778618435; called by muse, mutect2, varscan2
- EXOC7 | c.297G>A p.K99= | Silent (SNP) | VAF 44/190 reads (23%) | called by muse, mutect2, varscan2
- EZH2 | c.1731C>T p.V577= (on ENST00000460911 / NM_001203247.2; = p.V582= on NM_004456.5) | Silent (SNP) | VAF 78/345 reads (23%) | called by muse, mutect2, varscan2
- FAM71B | c.1317C>T p.P439= | Silent (SNP) | VAF 94/389 reads (24%) | catalogued as COSV57228929; called by muse, mutect2, varscan2
- FASTKD1 | c.1770G>A p.R590= | Silent (SNP) | VAF 58/286 reads (20%) | called by muse, mutect2, varscan2
- FBN1 | c.4224C>T p.C1408= | Silent (SNP) | VAF 54/245 reads (22%) | catalogued as COSV57326022; called by muse, mutect2, varscan2
- FHOD1 | c.1515C>T p.L505= | Silent (SNP) | VAF 126/509 reads (25%) | called by muse, mutect2, varscan2
- FICD | c.792C>T p.V264= | Silent (SNP) | VAF 86/356 reads (24%) | catalogued as rs758048881; called by muse, mutect2, varscan2
- FLNB | c.7428A>T p.L2476= | Silent (SNP) | VAF 27/173 reads (16%) | called by muse, varscan2
- FMO3 | c.579G>A p.G193= | Silent (SNP) | VAF 57/295 reads (19%) | called by muse, mutect2, varscan2
- FRMPD2 | c.3018G>A p.V1006= | Silent (SNP) | VAF 13/55 reads (24%) | called by muse, mutect2, varscan2
- GARRE1 | c.831C>T p.I277= | Silent (SNP) | VAF 56/249 reads (22%) | catalogued as rs770457248, COSV55103546; called by muse, mutect2, varscan2
- GDNF | c.420G>A p.L140= | Silent (SNP) | VAF 89/382 reads (23%) | catalogued as COSV58482152; called by muse, mutect2, varscan2
- GMNC | c.435G>A p.K145= | Silent (SNP) | VAF 148/371 reads (40%) | called by muse, mutect2, varscan2
- GOLGA6L6 | c.1929G>A p.T643= | Silent (SNP) | VAF 110/530 reads (21%) | catalogued as rs1359915385; called by muse, mutect2, varscan2
- GPANK1 | c.435C>T p.T145= | Silent (SNP) | VAF 170/667 reads (25%) | catalogued as rs1192262526; called by muse, mutect2, varscan2
- GPRASP1 | c.1410G>A p.G470= | Silent (SNP) | VAF 95/179 reads (53%) | catalogued as rs1288967751; called by muse, mutect2, varscan2
- GREB1 | c.3180C>T p.A1060= | Silent (SNP) | VAF 64/323 reads (20%) | called by muse, mutect2, varscan2
- GRID2IP | c.3528C>T p.F1176= | Silent (SNP) | VAF 66/287 reads (23%) | called by muse, mutect2, varscan2
- GRIN2B | c.3909C>T p.S1303= | Silent (SNP) | VAF 92/421 reads (22%) | catalogued as rs762775526; called by muse, mutect2, varscan2
- HDGF | c.204A>G p.E68= | Silent (SNP) | VAF 66/273 reads (24%) | called by muse, mutect2, varscan2
- HERC5 | c.2700C>T p.F900= | Silent (SNP) | VAF 73/270 reads (27%) | called by muse, mutect2, varscan2
- HM13 | c.297G>A p.E99= | Silent (SNP) | VAF 63/391 reads (16%) | called by muse, mutect2, varscan2
- HSFX1 | c.93C>T p.P31= | Silent (SNP) | VAF 84/416 reads (20%) | called by muse, mutect2, varscan2
- IGHA1 | c.714G>A p.E238= | Silent (SNP) | VAF 95/291 reads (33%) | catalogued as rs755400951; called by muse, mutect2, varscan2
- IL16 | c.963G>A p.L321= | Silent (SNP) | VAF 119/450 reads (26%) | called by muse, mutect2, varscan2
- IRAK2 | c.297C>T p.I99= | Silent (SNP) | VAF 65/239 reads (27%) | called by muse, mutect2, varscan2
- IRS1 | c.2961T>C p.G987= | Silent (SNP) | VAF 104/434 reads (24%) | called by muse, mutect2, varscan2
- ITGA2B | c.1677G>A p.Q559= | Silent (SNP) | VAF 109/488 reads (22%) | called by muse, mutect2, varscan2
- JPH4 | c.585C>T p.F195= | Silent (SNP) | VAF 100/318 reads (31%) | called by muse, mutect2, varscan2
- KAT6B | c.3780G>A p.R1260= | Silent (SNP) | VAF 88/389 reads (23%) | catalogued as rs773926507; called by muse, mutect2, varscan2
- KCNQ3 | c.1779C>T p.F593= | Silent (SNP) | VAF 96/284 reads (34%) | catalogued as COSV101196455; called by muse, mutect2, varscan2
- KL | c.264C>T p.S88= | Silent (SNP) | VAF 65/360 reads (18%) | called by muse, mutect2, varscan2
- KMT2D | c.13347C>G p.L4449= | Silent (SNP) | VAF 103/442 reads (23%) | called by muse, mutect2, varscan2
- KRTAP4-11 | c.540C>T p.V180= | Silent (SNP) | VAF 144/555 reads (26%) | called by muse, mutect2, varscan2
- MAP3K10 | c.825C>T p.I275= | Silent (SNP) | VAF 89/332 reads (27%) | catalogued as rs1398195005; called by muse, mutect2, varscan2
- MATK | c.375G>A p.G125= (on ENST00000310132 / NM_139355.3; = p.G126= on NM_002378.4) | Silent (SNP) | VAF 67/335 reads (20%) | called by muse, mutect2, varscan2
- METTL24 | c.651T>C p.I217= | Silent (SNP) | VAF 69/248 reads (28%) | called by muse, mutect2, varscan2
- METTL8 | c.676C>T p.L226= | Silent (SNP) | VAF 77/277 reads (28%) | called by muse, mutect2, varscan2
- MGA | c.3921G>A p.K1307= | Silent (SNP) | VAF 46/216 reads (21%) | called by muse, mutect2, varscan2
- MGAM | c.5149C>T p.L1717= | Silent (SNP) | VAF 77/337 reads (23%) | called by muse, mutect2, varscan2
- MICAL3 | c.531C>T p.I177= | Silent (SNP) | VAF 71/269 reads (26%) | catalogued as rs748706911, COSV52902491; called by muse, mutect2, varscan2
- MRPL55 | c.9C>A p.A3= | Silent (SNP) | VAF 72/312 reads (23%) | called by muse, mutect2, varscan2
- MTIF3 | c.183C>T p.T61= | Silent (SNP) | VAF 87/355 reads (25%) | catalogued as COSV66949743; called by muse, mutect2, varscan2
- MTTP | c.75T>A p.G25= | Silent (SNP) | VAF 60/259 reads (23%) | called by muse, mutect2, varscan2
- MUC16 | c.37233G>A p.R12411= | Silent (SNP) | VAF 46/189 reads (24%) | catalogued as COSV67454174; called by muse, mutect2, varscan2
- MUC16 | c.26361C>T p.I8787= | Silent (SNP) | VAF 67/356 reads (19%) | catalogued as rs1338987939, COSV67492345; called by muse, mutect2, varscan2
- MUC16 | c.16209G>A p.P5403= | Silent (SNP) | VAF 96/471 reads (20%) | catalogued as rs373387179; called by muse, mutect2, varscan2
- MUC16 | c.1737G>A p.G579= | Silent (SNP) | VAF 87/379 reads (23%) | catalogued as COSV67460195; called by muse, mutect2, varscan2
- NES | c.186C>T p.A62= | Silent (SNP) | VAF 117/425 reads (28%) | called by muse, mutect2, varscan2
- NET1 | c.1080C>T p.S360= (on ENST00000355029 / NM_001047160.3; = p.S306= on NM_005863.5) | Silent (SNP) | VAF 70/253 reads (28%) | catalogued as rs373843358; called by muse, mutect2, varscan2
- NOC2L | c.1671C>T p.F557= | Silent (SNP) | VAF 42/159 reads (26%) | catalogued as rs765132800; called by muse, mutect2
- NRK | c.3694C>T p.L1232= | Silent (SNP) | VAF 73/148 reads (49%) | called by muse, mutect2, varscan2
- NUGGC | c.1128G>A p.Q376= | Silent (SNP) | VAF 41/190 reads (22%) | called by muse, mutect2, varscan2
- OR10H5 | c.687C>T p.I229= | Silent (SNP) | VAF 61/367 reads (17%) | called by muse, mutect2, varscan2
- OR13A1 | c.969C>T p.F323= | Silent (SNP) | VAF 60/265 reads (23%) | catalogued as COSV65572230; called by muse, mutect2, varscan2
- OR2A25 | c.456C>T p.V152= | Silent (SNP) | VAF 79/345 reads (23%) | called by muse, mutect2, varscan2
- OR2T34 | c.720G>A p.R240= | Silent (SNP) | VAF 98/418 reads (23%) | catalogued as rs1276231691, COSV60900487; called by muse, mutect2, varscan2
- OR4C13 | c.480C>T p.F160= | Silent (SNP) | VAF 78/298 reads (26%) | catalogued as rs782002007, COSV73648688; called by muse, mutect2, varscan2
- OR51A4 | c.342C>T p.S114= | Silent (SNP) | VAF 82/628 reads (13%) | catalogued as rs1564812557; called by muse, mutect2, varscan2
- OR5D13 | c.759C>T p.F253= | Silent (SNP) | VAF 106/437 reads (24%) | called by muse, mutect2
- PALM2AKAP2 | c.2043C>T p.F681= (on ENST00000259318 / NM_001136562.3; = p.F912= on NM_007203.5) | Silent (SNP) | VAF 113/320 reads (35%) | called by muse, mutect2, varscan2
- PARP12 | c.1452C>T p.I484= | Silent (SNP) | VAF 56/217 reads (26%) | called by muse, mutect2, varscan2
- PCDHA1 | c.2202G>A p.P734= | Silent (SNP) | VAF 81/389 reads (21%) | catalogued as rs374247491, COSV65372814; called by mutect2, varscan2
- PCDHGB7 | c.399C>T p.F133= | Silent (SNP) | VAF 57/240 reads (24%) | catalogued as rs770068542; called by muse, mutect2, varscan2
- PCED1B | c.565C>T p.L189= | Silent (SNP) | VAF 81/366 reads (22%) | called by muse, mutect2, varscan2
- PCSK2 | c.1683G>A p.G561= | Silent (SNP) | VAF 193/499 reads (39%) | catalogued as COSV52743485; called by muse, mutect2, varscan2
- PEAR1 | c.2919G>A p.Q973= | Silent (SNP) | VAF 95/318 reads (30%) | called by muse, mutect2, varscan2
- PHOX2B | c.48C>T p.S16= | Silent (SNP) | VAF 82/335 reads (24%) | catalogued as rs1383504578; ClinVar: likely benign; called by muse, mutect2, varscan2
- PIGK | c.321T>C p.N107= | Silent (SNP) | VAF 31/320 reads (10%) | called by muse, mutect2
- PITRM1 | c.1590C>T p.S530= | Silent (SNP) | VAF 64/275 reads (23%) | catalogued as rs759304138; called by muse, mutect2, varscan2
- PLCG2 | c.1764C>T p.I588= | Silent (SNP) | VAF 65/285 reads (23%) | called by muse, mutect2, varscan2
- PLCXD3 | c.519G>A p.A173= | Silent (SNP) | VAF 86/379 reads (23%) | catalogued as rs377065100, COSV60605164; called by muse, mutect2, varscan2
- PNLDC1 | c.165C>T p.V55= | Silent (SNP) | VAF 78/232 reads (34%) | catalogued as rs757768329, COSV51708841; called by muse, mutect2, varscan2
- POM121C | c.2223C>T p.T741= (on ENST00000607367; = p.T499= on NM_001099415.3) | Silent (SNP) | VAF 93/306 reads (30%) | catalogued as rs1554471002; called by muse, varscan2
- POTEC | c.207C>T p.F69= | Silent (SNP) | VAF 132/537 reads (25%) | catalogued as rs1304491786, COSV100743704; called by muse, mutect2, varscan2
- PPIAL4G | c.267C>T p.I89= | Silent (SNP) | VAF 76/436 reads (17%) | called by muse, mutect2, varscan2
- PPP1R9A | c.2676G>A p.K892= | Silent (SNP) | VAF 65/327 reads (20%) | catalogued as rs374278543; called by muse, mutect2, varscan2
- PTK2B | c.1929G>A p.R643= | Silent (SNP) | VAF 77/340 reads (23%) | called by muse, mutect2, varscan2
- PTPRM | c.2601C>T p.A867= | Silent (SNP) | VAF 86/336 reads (26%) | catalogued as rs762045156; called by muse, mutect2, varscan2
- PYHIN1 | c.1302C>T p.S434= | Silent (SNP) | VAF 89/373 reads (24%) | catalogued as COSV63723934; called by muse, mutect2, varscan2
- RASGEF1A | c.1356C>T p.F452= | Silent (SNP) | VAF 73/304 reads (24%) | catalogued as rs765150963, COSV65667162; called by muse, mutect2, varscan2
- RBM47 | c.213C>T p.C71= | Silent (SNP) | VAF 105/460 reads (23%) | catalogued as COSV55934191; called by muse, mutect2, varscan2
- RD3 | c.97C>T p.L33= | Silent (SNP) | VAF 97/394 reads (25%) | called by muse, mutect2, varscan2
- RGS7 | c.273C>T p.F91= | Silent (SNP) | VAF 51/255 reads (20%) | catalogued as COSV58535015; called by muse, mutect2, varscan2
- RIMS2 | c.2889G>A p.V963= (on ENST00000666250 / NM_001348490.2; = p.V771= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 41/254 reads (16%) | called by muse, mutect2, varscan2
- ROCK1 | c.3399C>T p.I1133= | Silent (SNP) | VAF 37/228 reads (16%) | called by muse, mutect2, varscan2
- RTN4R | c.867C>T p.L289= | Silent (SNP) | VAF 120/447 reads (27%) | catalogued as rs757198909; called by muse, mutect2, varscan2
- RTP3 | c.174C>T p.C58= | Silent (SNP) | VAF 58/219 reads (26%) | catalogued as rs747002565; called by muse, mutect2, varscan2
- SCN7A | c.36C>T p.P12= | Silent (SNP) | VAF 58/244 reads (24%) | catalogued as rs267598979, COSV69274569; called by muse, mutect2, varscan2
- SEC13 | c.324G>C p.S108= (on ENST00000350697 / NM_183352.3; = p.S111= on NM_030673.4) | Silent (SNP) | VAF 32/227 reads (14%) | called by muse, mutect2, varscan2
- SEZ6L | c.1620C>T p.I540= | Silent (SNP) | VAF 61/354 reads (17%) | called by muse, mutect2, varscan2
- SIRPD | c.507C>T p.A169= | Silent (SNP) | VAF 158/435 reads (36%) | called by muse, mutect2, varscan2
- SLC14A2 | c.1389G>A p.K463= | Silent (SNP) | VAF 57/231 reads (25%) | called by muse, mutect2, varscan2
- SLIT1 | c.1440C>T p.I480= | Silent (SNP) | VAF 65/279 reads (23%) | catalogued as COSV99822359; called by muse, mutect2, varscan2
- SPHKAP | c.4284G>A p.L1428= | Silent (SNP) | VAF 61/317 reads (19%) | catalogued as COSV100763879; called by muse, mutect2, varscan2
- SPRR2G | c.75G>A p.E25= | Silent (SNP) | VAF 108/492 reads (22%) | called by muse, mutect2, varscan2
- SRGAP3 | c.222C>T p.F74= | Silent (SNP) | VAF 46/228 reads (20%) | called by muse, mutect2, varscan2
- SSC5D | c.3525C>T p.F1175= | Silent (SNP) | VAF 58/295 reads (20%) | catalogued as COSV67477344, COSV67477570; called by muse, mutect2, varscan2
- STARD9 | c.11524C>T p.L3842= | Silent (SNP) | VAF 92/325 reads (28%) | catalogued as rs1037750590; called by muse, mutect2, varscan2
- STAT6 | c.1020C>T p.I340= | Silent (SNP) | VAF 45/249 reads (18%) | called by muse, mutect2, varscan2
- STK11IP | c.1266C>T p.F422= | Silent (SNP) | VAF 89/372 reads (24%) | called by muse, mutect2, varscan2
- SULF2 | c.1731G>A p.K577= | Silent (SNP) | VAF 183/526 reads (35%) | catalogued as COSV63415110; called by muse, mutect2, varscan2
- SYT1 | c.108G>A p.K36= | Silent (SNP) | VAF 44/272 reads (16%) | called by muse, mutect2
- TACR3 | c.1224C>T p.S408= | Silent (SNP) | VAF 68/337 reads (20%) | catalogued as COSV59198652; called by muse, mutect2, varscan2
- TAS2R41 | c.378C>T p.F126= | Silent (SNP) | VAF 75/374 reads (20%) | called by muse, mutect2, varscan2
- TBC1D14 | c.531C>T p.I177= | Silent (SNP) | VAF 117/406 reads (29%) | called by muse, mutect2, varscan2
- TMDD1 | c.193C>A p.R65= | Silent (SNP) | VAF 87/358 reads (24%) | called by muse, mutect2, varscan2
- TMEM131 | c.753C>T p.D251= | Silent (SNP) | VAF 72/317 reads (23%) | called by muse, mutect2, varscan2
- TNFRSF9 | c.555G>A p.P185= | Silent (SNP) | VAF 46/204 reads (23%) | catalogued as COSV66349101; called by muse, mutect2, varscan2
- TRPM8 | c.816T>C p.T272= | Silent (SNP) | VAF 87/324 reads (27%) | catalogued as rs773861898; called by muse, mutect2, varscan2
- TSR1 | c.573G>A p.G191= | Silent (SNP) | VAF 56/206 reads (27%) | called by muse, mutect2, varscan2
- TTLL3 | c.597G>A p.Q199= | Silent (SNP) | VAF 71/308 reads (23%) | called by muse, mutect2, varscan2
- TTN | c.52404G>A p.V17468= (on ENST00000591111; = p.V10044= on NM_003319.4) | Silent (SNP) | VAF 67/269 reads (25%) | called by muse, mutect2, varscan2
- TTN | c.22440C>T p.F7480= (on ENST00000591111; = p.F6553= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 71/294 reads (24%) | catalogued as rs754815317, COSV59933248; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UBE2G2 | c.196T>C p.L66= | Silent (SNP) | VAF 63/261 reads (24%) | called by muse, mutect2, varscan2
- UNC79 | c.6306G>A p.T2102= (on ENST00000393151 / NM_001346218.2; = p.T1925= on NM_020818.5) | Silent (SNP) | VAF 87/278 reads (31%) | catalogued as rs779988693, COSV56390148; called by muse, mutect2, varscan2
- USP40 | c.2580C>T p.I860= | Silent (SNP) | VAF 46/195 reads (24%) | catalogued as rs368616040; called by muse, mutect2, varscan2
- VWA5B2 | c.3558G>A p.E1186= | Silent (SNP) | VAF 109/624 reads (17%) | catalogued as rs772105305; called by muse, mutect2
- WSCD2 | c.57C>T p.F19= | Silent (SNP) | VAF 72/326 reads (22%) | called by muse, mutect2, varscan2
- YKT6 | c.24C>A p.V8= | Silent (SNP) | VAF 52/261 reads (20%) | called by mutect2, varscan2
- ZMAT4 | c.174G>A p.K58= | Silent (SNP) | VAF 76/312 reads (24%) | called by muse, mutect2, varscan2
- ZNF45 | c.1695C>T p.F565= | Silent (SNP) | VAF 87/398 reads (22%) | called by muse, mutect2, varscan2
- ZNF776 | c.1332G>A p.K444= | Silent (SNP) | VAF 100/416 reads (24%) | called by muse, mutect2, varscan2
- BRD4 | c.2158+388C>T | Intron (SNP) | VAF 51/242 reads (21%) | called by muse, mutect2, varscan2
- CCNYL2 | chr10:42475856 G>A | 5'Flank (SNP) | VAF 63/295 reads (21%) | catalogued as rs998527774; called by muse, mutect2, varscan2
- DCC | c.4255-149C>T | Intron (SNP) | VAF 61/280 reads (22%) | called by muse, mutect2, varscan2
- DNAH2 | c.1170+752C>A | Intron (SNP) | VAF 75/312 reads (24%) | called by muse, mutect2, varscan2
- GMEB2 | c.*1230C>T | 3'UTR (SNP) | VAF 125/589 reads (21%) | catalogued as COSV56608392; called by muse, mutect2, varscan2
- HBD | chr11:5232783 G>A | 3'Flank (SNP) | VAF 57/255 reads (22%) | catalogued as rs771686740, COSV99496509, COSV99496860; called by muse, mutect2, varscan2
- IGFN1 | c.1242-17C>T | Intron (SNP) | VAF 92/414 reads (22%) | catalogued as rs375886100; called by muse, mutect2, varscan2
- INTS11 | c.429+333G>A | Intron (SNP) | VAF 48/426 reads (11%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1514+22053C>T | Intron (SNP) | VAF 64/308 reads (21%) | called by muse, mutect2
- LINC00632 | n.404C>G | RNA (SNP) | VAF 87/208 reads (42%) | called by muse, mutect2, varscan2
- MRGPRF | c.48+93C>T | Intron (SNP) | VAF 95/310 reads (31%) | catalogued as rs745782519; called by mutect2, varscan2
- POLR3B | c.2714-9C>T | Intron (SNP) | VAF 85/421 reads (20%) | called by muse, mutect2, varscan2
- PVT1 | n.903+18T>C | Intron (SNP) | VAF 22/402 reads (5%) | called by muse, mutect2
- SIRPB1 | c.*493A>T | 3'UTR (SNP) | VAF 71/448 reads (16%) | called by muse, mutect2, varscan2
- TIGIT | chr3:114293875 G>A | 5'Flank (SNP) | VAF 121/389 reads (31%) | called by muse, mutect2, varscan2
- TK2 | c.64-4911G>C | Intron (SNP) | VAF 67/298 reads (22%) | called by muse, mutect2, varscan2
- TTC6 | c.358-1366C>T | Intron (SNP) | VAF 51/186 reads (27%) | catalogued as rs1407588653; called by muse, mutect2, varscan2
